Somatic mutation profile of tumor specimen TARGET-10-PARDDM-09A (aliquot TARGET-10-PARDDM-09A-01D) from TARGET case TARGET-10-PARDDM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,751 days).
Specimen TARGET-10-PARDDM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bc12b69-a834-4406-8967-447e94006a98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDDM-10A (Blood Derived Normal), aliquot TARGET-10-PARDDM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ec2ebe4-119d-4568-8a15-21eeb7cda286

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Intron 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1736T>C p.V579A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057520022, COSV54065509, COSV54077224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HDGFL2 | c.122C>G p.P41R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56682206; called by muse, mutect2, varscan2
- ISM1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546009979; called by muse, mutect2, varscan2
- WWC1 | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54645152; called by muse, mutect2, varscan2
- DSG1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2
- H2AC16 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- NPAS3 | c.1528G>A p.D510N (on ENST00000356141 / NM_001164749.2; = p.D478N on NM_022123.3) | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ALPI | c.1165C>A p.R389= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs138329965; called by muse, varscan2
- CD4 | c.1002C>T p.T334= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- FSHB | c.321C>T p.S107= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs542360180, COSV54222864; called by muse, mutect2, varscan2
- RGS18 | c.111C>A p.A37= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as rs1394376843, COSV66509509; called by muse, mutect2
- CSNK1D | c.886-640C>T | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs1012847286; called by muse, mutect2, varscan2
- EDNRA | c.-59del | 5'UTR (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel
- HOXA3 | c.-4C>T | 5'UTR (SNP) | VAF 13/29 reads (45%) | catalogued as COSV57825362; called by muse, mutect2, varscan2
- NRXN1 | c.3546+29201C>T | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as rs574745919; called by muse, mutect2
- SPICE1 | c.*69A>C | 3'UTR (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
